Somatic mutation profile of tumor specimen TARGET-40-0A4HXO-01A (aliquot TARGET-40-0A4HXO-01A-01D) from TARGET case TARGET-40-0A4HXO, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 24.8 years (9,058 days).
Specimen TARGET-40-0A4HXO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1814fc36-6360-4f50-8606-21659f5539c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-0A4HXO-10A (Blood Derived Normal), aliquot TARGET-40-0A4HXO-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/95b16a67-de8e-45a9-b76a-d8f204f8ee1c

The open-access MAF lists 17 somatic variants for this specimen: 13 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, RNA 1, Silent 1, Splice Site 1, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIAA1210 | c.1340C>T p.T447I | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs375207301; called by muse, mutect2, varscan2
- NF1 | c.2132G>A p.R711H | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as rs1479669686; ClinVar: uncertain significance; called by muse, mutect2
- PENK | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.055); catalogued as COSV59242776; called by muse, mutect2, varscan2
- POLD1 | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV70954473; called by muse, mutect2
- ROBO3 | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1414782646; called by muse, mutect2
- TAF1L | c.2173C>T p.R725W | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as rs753755235, COSV54266450; called by muse, mutect2, varscan2
- CD72 | c.604G>C p.E202Q | Missense Mutation (SNP) | VAF 10/175 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.744); called by muse, mutect2
- CSTF2 | c.989G>T p.R330L | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- FLOT1 | c.44-1G>T p.X15_splice | Splice Site (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2
- OR1P1 | c.275T>A p.V92E | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- SIGLEC10 | c.1980G>C p.E660D | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- SIRT1 | c.1493C>T p.A498V | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.028); called by muse, mutect2
- SLITRK5 | c.529C>A p.H177N | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT tolerated (0.64); PolyPhen benign (0.012); called by muse, mutect2
- RELL1 | c.135G>T p.P45= | Silent (SNP) | VAF 38/165 reads (23%) | called by muse, mutect2, varscan2
- AC073648.3 | n.93C>T | RNA (SNP) | VAF 10/124 reads (8%) | catalogued as rs1291893315; called by muse, mutect2
- ASPH | c.322+4916A>T | Intron (SNP) | VAF 16/91 reads (18%) | called by muse, mutect2, varscan2
- TENT4B | c.*122G>T | 3'UTR (SNP) | VAF 7/25 reads (28%) | called by muse, varscan2
